Somatic mutation profile of cancer-model specimen HCM-BROD-0685-C71-85A (3D Neurosphere, passage 11; aliquot HCM-BROD-0685-C71-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-BROD-0685-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.8 years (25,506 days).
Specimen HCM-BROD-0685-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e66987-0389-43ee-ad46-325114118ef0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0685-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0685-C71-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e967647-fcfb-4f71-aedc-3951a8d05779

The open-access MAF lists 77 somatic variants for this specimen: 50 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 23, Nonsense Mutation 7, Splice Site 2, 3'UTR 2, Intron 1, Nonstop Mutation 1, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 144/144 reads (100%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 473/474 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOBEC3B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 91/694 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs770453697; called by muse, mutect2, varscan2
- CPAMD8 | c.3998C>G p.S1333* (on ENST00000651564; = p.S1286* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 112/496 reads (23%) | catalogued as COSV101488557; called by muse, mutect2
- DDC | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 198/582 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV63565075; called by muse, varscan2
- DYNC1I1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 134/335 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as rs369627655; called by muse, mutect2, varscan2
- GPT | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 417/790 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs530505425; called by muse, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HLA-DRA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 207/385 reads (54%) | catalogued as rs754420534, COSV66623242; called by muse, varscan2
- HRNR | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 212/459 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs201404604, COSV64255160; called by muse, varscan2
- HUNK | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776863029; called by muse, mutect2, varscan2
- ITGAX | c.2119G>A p.G707R | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs368436373, COSV51650226, COSV99192014; called by muse, varscan2
- KCNK13 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 47/498 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs369202821, COSV56418467; called by muse, mutect2
- MXRA5 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 321/321 reads (100%) | catalogued as rs527784574, COSV54222197; called by muse, mutect2, varscan2
- MYH13 | c.2780C>T p.T927M | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs768267700; called by muse, mutect2, varscan2
- NALCN | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 65/118 reads (55%) | catalogued as rs1335710703, COSV51946337; called by muse, varscan2
- NIPBL | c.7220G>T p.R2407L | Missense Mutation (SNP) | VAF 125/288 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148618, COSV56952574; called by muse, mutect2, varscan2
- NRK | c.2418C>T p.S806= | Splice Region (SNP) | VAF 122/122 reads (100%) | catalogued as rs774915551; called by muse, mutect2, varscan2
- OR14I1 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 195/378 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs766507577, COSV100700498; called by muse, varscan2
- PGK2 | c.971A>G p.H324R | Missense Mutation (SNP) | VAF 169/346 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59163494; called by muse, varscan2
- PTEN | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 133/134 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as CM142085, COSV64291830; called by muse, mutect2, varscan2
- RHEX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 155/469 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs531574406, COSV58980514; called by muse, mutect2, varscan2
- RHOV | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 275/542 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239281442; called by muse, mutect2, varscan2
- RNF169 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 240/729 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV55132637; called by muse, mutect2, varscan2
- SAMD1 | c.931+1G>A p.X311_splice | Splice Site (SNP) | VAF 249/482 reads (52%) | catalogued as rs1170878325; called by muse, mutect2, varscan2
- TOPAZ1 | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as rs752812035; called by muse, mutect2, varscan2
- ALPK3 | c.780C>A p.H260Q | Missense Mutation (SNP) | VAF 119/544 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, varscan2
- CP | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 122/278 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DTX3L | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 235/235 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EML5 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 140/271 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, varscan2
- FOXD4L4 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 188/1497 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- IZUMO3 | c.421G>T p.G141C (on ENST00000543880 / NM_001365008.2; = p.G135C on NM_001271706.1) | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KBTBD6 | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF20A | c.796_798del p.S266del | In Frame Del (DEL) | VAF 108/257 reads (42%) | called by pindel, varscan2
- MMRN1 | c.3685T>A p.*1229Kext*43 | Nonstop Mutation (SNP) | VAF 95/95 reads (100%) | called by muse, mutect2, varscan2
- MUC17 | c.6282C>G p.I2094M | Missense Mutation (SNP) | VAF 89/492 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, varscan2
- OR52E5 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- OR5AC2 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 200/202 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.309); called by muse, varscan2
- PMS2 | c.756T>A p.C252* | Nonsense Mutation (SNP) | VAF 152/494 reads (31%) | called by muse, mutect2, varscan2
- PRSS36 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 234/491 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- RGL1 | c.2005-1G>T p.X669_splice (on ENST00000360851 / NM_001297672.2; = p.X704_splice on NM_015149.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 72/267 reads (27%) | called by muse, mutect2, varscan2
- RPAP1 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 158/328 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SEMA3E | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, varscan2
- SH3GL3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- SLAMF7 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, varscan2
- SPECC1L | c.3296C>A p.P1099H | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ST6GAL2 | c.537G>C p.R179S | Missense Mutation (SNP) | VAF 186/785 reads (24%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCHH | c.2361G>T p.R787S | Missense Mutation (SNP) | VAF 382/759 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- TRIM15 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 209/434 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF865 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 75/950 reads (8%) | SIFT deleterious (0.02); called by muse, mutect2
- A1CF | c.1773T>C p.Y591= (on ENST00000373993 / NM_138932.2; = p.Y583= on NM_014576.4) | Silent (SNP) | VAF 111/111 reads (100%) | catalogued as rs1205244851; called by muse, mutect2, varscan2
- CUL4B | c.1614G>A p.E538= | Silent (SNP) | VAF 171/171 reads (100%) | called by muse, mutect2, varscan2
- EIF2B4 | c.463C>T p.L155= (on ENST00000347454 / NM_001034116.2; = p.L154= on NM_015636.3) | Silent (SNP) | VAF 168/386 reads (44%) | called by muse, mutect2, varscan2
- EP400 | c.8937G>A p.P2979= | Silent (SNP) | VAF 285/449 reads (63%) | catalogued as rs748552218; called by muse, varscan2
- F13B | c.1983A>G p.T661= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- HRNR | c.2001C>T p.S667= | Silent (SNP) | VAF 250/623 reads (40%) | catalogued as rs374849852; called by muse, varscan2
- ITGA4 | c.1278G>A p.S426= | Silent (SNP) | VAF 123/267 reads (46%) | catalogued as rs201581651, COSV52001707, COSV99275884; called by muse, mutect2, varscan2
- MSLN | c.1050C>T p.D350= | Silent (SNP) | VAF 71/297 reads (24%) | catalogued as rs772391015; called by muse, varscan2
- NMUR2 | c.459C>T p.R153= | Silent (SNP) | VAF 205/510 reads (40%) | catalogued as rs1004624182, COSV99677400; called by muse, mutect2, varscan2
- NPHS1 | c.2013C>T p.S671= | Silent (SNP) | VAF 331/680 reads (49%) | catalogued as rs775801945, COSV62287390; called by muse, mutect2, varscan2
- OR2Z1 | c.762C>T p.A254= | Silent (SNP) | VAF 142/622 reads (23%) | catalogued as rs368422189; called by muse, varscan2
- PCDHGA7 | c.1338C>T p.N446= | Silent (SNP) | VAF 162/400 reads (41%) | catalogued as COSV53916861; called by muse, varscan2
- PKLR | c.822C>T p.F274= | Silent (SNP) | VAF 532/969 reads (55%) | catalogued as rs1233630203; called by muse, mutect2, varscan2
- PLXNA2 | c.4683C>T p.A1561= | Silent (SNP) | VAF 198/387 reads (51%) | called by muse, mutect2, varscan2
- PRSS45P | c.741C>A p.L247= | Silent (SNP) | VAF 107/239 reads (45%) | catalogued as COSV101373924; called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 164/525 reads (31%) | catalogued as rs1190794791, COSV60978927; called by muse, varscan2
- REELD1 | c.747A>G p.P249= | Silent (SNP) | VAF 196/199 reads (98%) | called by muse, varscan2
- RSPH4A | c.1683C>T p.N561= | Silent (SNP) | VAF 122/269 reads (45%) | catalogued as rs1451660000; called by muse, mutect2, varscan2
- SCN5A | c.5373C>T p.F1791= (on ENST00000333535 / NM_198056.3; = p.F1790= on NM_000335.5) | Silent (SNP) | VAF 76/186 reads (41%) | catalogued as rs372380415; ClinVar: likely benign; called by muse, varscan2
- SEPTIN5 | c.855C>T p.N285= | Silent (SNP) | VAF 121/339 reads (36%) | called by muse, mutect2, varscan2
- SSC5D | c.1137C>T p.A379= | Silent (SNP) | VAF 380/750 reads (51%) | called by muse, mutect2, varscan2
- TACR1 | c.561T>C p.H187= | Silent (SNP) | VAF 55/244 reads (23%) | catalogued as rs1210292164; called by muse, mutect2, varscan2
- WDR13 | c.1434C>T p.I478= | Silent (SNP) | VAF 122/244 reads (50%) | catalogued as COSV54331412; called by muse, varscan2
- CD55 | c.1081+1102C>T | Intron (SNP) | VAF 105/181 reads (58%) | catalogued as rs1421288809; called by muse, varscan2
- DEFB110 | c.*1C>T | 3'UTR (SNP) | VAF 106/211 reads (50%) | catalogued as rs761064329, COSV100953811; called by muse, mutect2, varscan2
- POU2F2 | c.*238G>A | 3'UTR (SNP) | VAF 271/546 reads (50%) | catalogued as rs1456130043; called by muse, varscan2
- SLC22A17 | n.676C>T | RNA (SNP) | VAF 212/422 reads (50%) | catalogued as rs376977274; called by muse, mutect2, varscan2
